Somatic mutation profile of tumor specimen TCGA-CV-5434-01A (aliquot TCGA-CV-5434-01A-01D-1683-08) from TCGA case TCGA-CV-5434, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 60.7 years (22,182 days).
Specimen TCGA-CV-5434-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a2d296b-3f51-4269-861f-e77ae23643e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-5434-10A (Blood Derived Normal), aliquot TCGA-CV-5434-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce93c0dc-1dc9-4e53-bead-556c1e366a2f

The open-access MAF lists 144 somatic variants for this specimen: 115 protein-altering or splice-affecting, 26 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 99, Silent 26, Nonsense Mutation 8, Splice Site 3, Frame Shift Ins 3, Intron 1, In Frame Del 1, 5'UTR 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.4398G>C p.W1466C | Missense Mutation (SNP) | VAF 28/80 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV54327842, COSV54327957, COSV54334788; called by muse, mutect2, varscan2
- KEAP1 | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 18/33 reads (55%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV50260643, COSV50262012; called by muse, mutect2
- PAX5 | c.77T>G p.V26G | Missense Mutation (SNP) | VAF 12/96 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs926053251, COSV63904854, COSV63909409; called by muse, varscan2
- TP53 | c.707A>G p.Y236C | Missense Mutation (SNP) | VAF 35/67 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs730882026, CM004907, COSV52662150, COSV52735723, COSV53167431; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 15/43 reads (35%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACBD6 | c.385-2A>T p.X129_splice | Splice Site (SNP) | VAF 14/110 reads (13%) | catalogued as COSV100852512; called by muse, mutect2, varscan2
- AKR1C4 | c.370C>A p.P124T | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99578727; called by muse, mutect2, varscan2
- ALDH1A2 | c.71A>G p.H24R | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.01); catalogued as COSV51080692, COSV99990763; called by muse, mutect2, varscan2
- ARHGAP35 | c.1240C>T p.Q414* | Nonsense Mutation (SNP) | VAF 83/118 reads (70%) | catalogued as COSV68332652; called by muse, mutect2, varscan2
- ASB4 | c.883G>C p.V295L | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.621); catalogued as rs780865545, COSV100367178; called by muse, mutect2, varscan2
- ATF7IP | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99038743; called by muse, mutect2, varscan2
- ATP8B4 | c.809A>C p.D270A | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99465686; called by muse, mutect2
- BSN | c.2872C>T p.R958W | Missense Mutation (SNP) | VAF 45/61 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99608597; called by muse, mutect2, varscan2
- C21orf58 | c.326G>T p.R109L | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99388053; called by muse, varscan2
- CACNG4 | c.507C>A p.D169E | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.785); catalogued as COSV100047615; called by muse, varscan2
- CBLB | c.986A>G p.Y329C | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99913513, COSV99914173; called by muse, mutect2, varscan2
- CCHCR1 | c.1470G>C p.E490D | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.257); catalogued as COSV100885645; called by muse, mutect2, varscan2
- CCNB3 | c.618T>A p.F206L | Missense Mutation (SNP) | VAF 38/42 reads (90%) | SIFT tolerated (0.34); PolyPhen benign (0.429); catalogued as COSV99329122; called by muse, mutect2, varscan2
- CELSR2 | c.1397C>T p.T466M | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.049); catalogued as rs752173128, COSV99603940; called by mutect2, varscan2
- COL24A1 | c.1067T>G p.I356S | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs1261918838, COSV100993406; called by muse, mutect2, varscan2
- COL4A5 | c.2773G>A p.D925N | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV60355654; called by muse, mutect2, varscan2
- CSPP1 | c.2809C>T p.R937C (on ENST00000676605; = p.R896C on NM_024790.6) | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs757750162, COSV51580167; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DDX54 | c.2270G>C p.R757P | Missense Mutation (SNP) | VAF 60/170 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.362); catalogued as COSV100013917, COSV58373149; called by muse, mutect2, varscan2
- DHX33 | c.460A>G p.T154A | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.041); catalogued as COSV99834380; called by muse, mutect2, varscan2
- DIDO1 | c.4774G>A p.E1592K | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.003); catalogued as rs991037740, COSV99825983; called by muse, mutect2, varscan2
- DNAH1 | c.2392C>G p.P798A | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as COSV101325896; called by muse, mutect2, varscan2
- DPF3 | c.417C>G p.I139M | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.037); catalogued as COSV100818586; called by muse, mutect2, varscan2
- ELK3 | c.525dup p.V176Rfs*14 | Frame Shift Ins (INS) | VAF 10/64 reads (16%) | catalogued as rs769175197; called by mutect2, varscan2
- ERBB2 | c.545C>T p.T182I | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV99508047; called by muse, mutect2, varscan2
- F13B | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 46/324 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100803298; called by muse, mutect2, varscan2
- FAT1 | c.11218G>T p.G3740* | Nonsense Mutation (SNP) | VAF 19/27 reads (70%) | catalogued as COSV71675681; called by muse, mutect2, varscan2
- FBXO44 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs1381865573, COSV99278751; called by muse, mutect2, varscan2
- FCGR3A | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 35/300 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100914664; called by muse, mutect2, varscan2
- FGD2 | c.1531C>T p.L511F | Missense Mutation (SNP) | VAF 37/45 reads (82%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV99236197; called by muse, mutect2, varscan2
- FREM2 | c.4540G>T p.G1514* | Nonsense Mutation (SNP) | VAF 17/81 reads (21%) | catalogued as COSV54841741; called by muse, mutect2, varscan2
- GABRB1 | c.1399G>T p.V467F | Missense Mutation (SNP) | VAF 51/80 reads (64%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.875); catalogued as COSV54974186, COSV99040356, COSV99781801; called by muse, mutect2, varscan2
- GAPVD1 | c.2126A>G p.E709G | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99783243; called by muse, mutect2, varscan2
- GFUS | c.279G>T p.M93I | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101437056; called by muse, mutect2, varscan2
- GIGYF1 | c.104A>C p.K35T | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99309446; called by muse, mutect2, varscan2
- GLCCI1 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 55/220 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as COSV99780437; called by muse, mutect2, varscan2
- GPR141 | c.325A>G p.I109V | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as COSV100550339; called by muse, mutect2, varscan2
- GPR152 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs760895810, COSV100351434; called by muse, mutect2
- HAUS6 | c.1531G>A p.D511N | Missense Mutation (SNP) | VAF 63/184 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1443985735, COSV100997845; called by muse, varscan2
- HCFC2 | c.1830G>T p.L610F | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.216); catalogued as COSV99983087; called by muse, mutect2, varscan2
- IMPG2 | c.266T>A p.V89E | Missense Mutation (SNP) | VAF 73/105 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99515643; called by muse, mutect2, varscan2
- ITPRID2 | c.2951G>A p.R984H | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as rs369300058; called by muse, mutect2, varscan2
- ITPRIPL1 | c.1316C>T p.A439V (on ENST00000439118 / NM_001008949.3; = p.A447V on NM_178495.6) | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as COSV100742194; called by muse, mutect2, varscan2
- KCNJ10 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 77/166 reads (46%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.564); catalogued as rs1131691880, COSV100927925; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF1A | c.1624G>A p.V542I | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373891682; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLK4 | c.576C>A p.C192* | Nonsense Mutation (SNP) | VAF 60/118 reads (51%) | catalogued as COSV100133640, COSV60675642; called by muse, mutect2, varscan2
- LAMA2 | c.4037G>A p.G1346E | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70338493; called by muse, mutect2, varscan2
- LRRTM1 | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.776); catalogued as COSV99702599; called by muse, mutect2, varscan2
- MAGI2 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 70/115 reads (61%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.999); catalogued as rs762606410, COSV100833411; called by muse, mutect2, varscan2
- MAP2K3 | c.793C>T p.R265W (on ENST00000342679 / NM_145109.3; = p.R236W on NM_002756.4) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs1197448393, COSV57569288; called by muse, mutect2
- MAST4 | c.1856G>A p.R619Q (on ENST00000403625 / NM_001164664.2; = p.R430Q on NM_015183.3) | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1264103819, COSV99844342; called by muse, mutect2, varscan2
- MCHR2 | c.678G>T p.E226D | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV56003562, COSV99912056; called by muse, mutect2, varscan2
- MGAM | c.1921C>A p.P641T | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.36); catalogued as COSV101527513, COSV72075394; called by muse, mutect2, varscan2
- MMP12 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58259610; called by muse, mutect2, varscan2
- MPP6 | c.863G>A p.R288K | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99757540; called by muse, mutect2, varscan2
- NUMB | c.1092C>A p.F364L (on ENST00000355058; = p.F353L on NM_003744.5) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100679715; called by muse, mutect2
- OPRD1 | c.317G>A p.S106N | Missense Mutation (SNP) | VAF 54/75 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV99330348; called by muse, mutect2, varscan2
- OR10R2 | c.341T>C p.F114S | Missense Mutation (SNP) | VAF 145/268 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.623); catalogued as COSV100936793; called by muse, mutect2, varscan2
- OR1N2 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 100/166 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV65460257; called by muse, mutect2, varscan2
- OR6K2 | c.474G>C p.E158D | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV100656800; called by muse, mutect2, varscan2
- PDCL | c.219G>C p.E73D | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV99414134; called by muse, mutect2, varscan2
- PFAS | c.3181C>T p.P1061S | Missense Mutation (SNP) | VAF 81/210 reads (39%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV100118951; called by muse, mutect2, varscan2
- PIN1 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.4); catalogued as COSV99321819; called by muse, mutect2, varscan2
- PKDREJ | c.4330A>G p.I1444V | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV99478930; called by muse, mutect2, varscan2
- PLCH1 | c.4466C>A p.P1489H (on ENST00000340059 / NM_001130960.2; = p.P1481H on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100396971; called by muse, mutect2, varscan2
- PPP1R26 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as rs754686666, COSV100777993, COSV63356436; called by muse, mutect2, varscan2
- PROM2 | c.1567G>A p.G523R | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100469030; called by muse, mutect2, varscan2
- PRSS27 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1021018570, COSV100234537; called by muse, mutect2, varscan2
- PRSS48 | c.954G>C p.E318D | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.001); catalogued as COSV101490173; called by muse, mutect2
- PTPRB | c.5720G>T p.G1907V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99717553; called by muse, mutect2, varscan2
- PTPRR | c.1360-2A>T p.X454_splice | Splice Site (SNP) | VAF 16/47 reads (34%) | catalogued as COSV51727349; called by muse, mutect2, varscan2
- RAB3GAP1 | c.2281G>A p.A761T | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99921162; called by muse, mutect2, varscan2
- RIMBP2 | c.2536G>A p.E846K | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.11); catalogued as rs138034003; called by muse, mutect2, varscan2
- SCLT1 | c.15C>G p.I5M | Missense Mutation (SNP) | VAF 34/50 reads (68%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV99828105; called by muse, mutect2, varscan2
- SH3BGRL2 | c.236A>T p.Y79F | Missense Mutation (SNP) | VAF 44/65 reads (68%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.858); catalogued as COSV100877620; called by muse, mutect2, varscan2
- SLC13A1 | c.659A>T p.K220M | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV99520970; called by muse, mutect2, varscan2
- SLC7A11 | c.1060A>G p.I354V | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT tolerated (0.43); PolyPhen benign (0.05); catalogued as COSV99763190; called by muse, mutect2, varscan2
- SLITRK3 | c.2478G>T p.Q826H | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.969); catalogued as COSV99579317; called by muse, mutect2, varscan2
- SLITRK3 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as rs998593651, COSV53846053; called by muse, mutect2
- SP100 | c.2282dup p.K762Efs*21 | Frame Shift Ins (INS) | VAF 18/35 reads (51%) | catalogued as rs762056038; called by mutect2, varscan2
- ST8SIA1 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 76/175 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.076); catalogued as COSV99683193; called by muse, mutect2, varscan2
- SUN5 | c.481A>T p.S161C | Missense Mutation (SNP) | VAF 49/332 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); catalogued as COSV100644835; called by muse, mutect2, varscan2
- TASOR | c.3496G>A p.V1166I (on ENST00000355628 / NM_001365636.2; = p.V790I on NM_015224.3) | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1307352328, COSV62928052; called by muse, mutect2, varscan2
- THAP5 | c.533C>G p.S178C (on ENST00000415914 / NM_001130475.3; = p.S136C on NM_182529.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV99974504; called by muse, mutect2
- TMEM150B | c.311T>A p.V104E | Missense Mutation (SNP) | VAF 64/77 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100442355; called by muse, mutect2, varscan2
- TMEM184A | c.348C>A p.Y116* | Nonsense Mutation (SNP) | VAF 35/56 reads (63%) | catalogued as COSV99868322; called by muse, mutect2, varscan2
- TRIML2 | c.463T>C p.F155L | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.67); PolyPhen benign (0.205); catalogued as COSV100456081; called by muse, mutect2, varscan2
- TRPM3 | c.3638G>T p.R1213L (on ENST00000357533 / NM_001366142.2; = p.R1068L on NM_020952.6) | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as COSV100677469; called by muse, mutect2, varscan2
- TUBA3C | c.3+1G>A p.X1_splice | Splice Site (SNP) | VAF 18/30 reads (60%) | catalogued as COSV101262798; called by muse, mutect2, varscan2
- UBAP2 | c.1660C>A p.P554T | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV100671473; called by muse, mutect2, varscan2
- USH2A | c.4580A>G p.Y1527C | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.286); catalogued as COSV100235606; called by muse, mutect2, varscan2
- USP22 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.284); catalogued as rs1195230403, COSV54948753; called by muse, mutect2, varscan2
- VPS50 | c.2351T>G p.V784G | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100004844; called by muse, mutect2, varscan2
- WDR7 | c.1642C>T p.R548* | Nonsense Mutation (SNP) | VAF 22/60 reads (37%) | catalogued as COSV99589537; called by muse, mutect2, varscan2
- ZEB2 | c.151G>A p.G51S | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as rs749173524, COSV100355354, COSV100356105, COSV57963492; called by muse, mutect2, varscan2
- ZHX3 | c.1400C>T p.T467M | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as rs1046429056, COSV100476095; called by muse, mutect2, varscan2
- ZMAT1 | c.748T>A p.L250M | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.328); catalogued as COSV100858818; called by muse, mutect2, varscan2
- ZNF100 | c.26G>A p.C9Y | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs1328129021, COSV100841287; called by muse, mutect2, varscan2
- ZNF208 | c.2713A>C p.T905P | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.366); catalogued as rs376009484, COSV101237035; called by mutect2, varscan2
- ZNF276 | c.487G>A p.G163S (on ENST00000443381 / NM_001113525.2; = p.G88S on NM_152287.4) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.68); catalogued as rs748405201, COSV57065622; called by muse, mutect2, varscan2
- ZNF320 | c.1034A>T p.E345V | Missense Mutation (SNP) | VAF 67/94 reads (71%) | SIFT tolerated (0.34); PolyPhen benign (0.066); catalogued as COSV101206866; called by muse, mutect2, varscan2
- ZNF451 | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 16/62 reads (26%) | catalogued as rs752623979, COSV62600202; called by muse, mutect2, varscan2
- ZNF511 | c.449G>A p.G150D | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV100756792, COSV62920248; called by muse, mutect2, varscan2
- ZNF707 | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.842); catalogued as rs534396047, COSV100690616; called by muse, mutect2, varscan2
- ZNF750 | c.266A>T p.K89M | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV99489778; called by muse, mutect2, varscan2
- ZSCAN1 | c.1057C>T p.R353W | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as rs372351161, COSV56603506, COSV56605032, COSV99991543; called by muse, mutect2, varscan2
- ABCC9 | c.1412_1417del p.Y471_I473delinsF | In Frame Del (DEL) | VAF 11/37 reads (30%) | called by mutect2, pindel, varscan2
- ISLR2 | c.62del p.P21Rfs*33 | Frame Shift Del (DEL) | VAF 17/67 reads (25%) | called by mutect2, pindel, varscan2
- KMT2D | c.858_859insGT p.K287Vfs*18 | Frame Shift Ins (INS) | VAF 37/125 reads (30%) | called by mutect2, pindel, varscan2
- MYO19 | c.1407C>G p.N469K | Missense Mutation (SNP) | VAF 44/79 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- PRAMEF15 | c.374G>C p.G125A | Missense Mutation (SNP) | VAF 130/197 reads (66%) | SIFT tolerated (0.79); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCC11 | c.861G>A p.S287= | Silent (SNP) | VAF 29/156 reads (19%) | catalogued as rs374693833; called by muse, mutect2, varscan2
- ACSM4 | c.624C>T p.F208= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs770046219, COSV68067333; called by muse, mutect2, varscan2
- AP3D1 | c.1200C>T p.I400= | Silent (SNP) | VAF 30/58 reads (52%) | catalogued as COSV100642712; called by muse, mutect2, varscan2
- CYP3A5 | c.951T>C p.T317= | Silent (SNP) | VAF 17/124 reads (14%) | catalogued as COSV99769810; called by muse, mutect2, varscan2
- ECE1 | c.729C>G p.A243= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs763305486, COSV99941903; called by muse, mutect2, varscan2
- ERN1 | c.2307T>A p.S769= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as COSV101458448; called by muse, mutect2, varscan2
- FAM181B | c.156G>T p.S52= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100235094; called by muse, mutect2, varscan2
- FOXF2 | c.1263C>T p.P421= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as COSV99453263; called by muse, mutect2, varscan2
- FREM2 | c.4539T>C p.D1513= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as rs776853675, COSV99748940; called by muse, mutect2, varscan2
- GDAP1 | c.984G>A p.L328= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV99619585; called by muse, mutect2, varscan2
- GPRIN2 | c.1104G>T p.L368= | Silent (SNP) | VAF 11/109 reads (10%) | catalogued as COSV100966396; called by muse, mutect2, varscan2
- KDELR1 | c.399G>A p.P133= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs202051456; called by muse, mutect2, varscan2
- MECOM | c.516G>T p.S172= (on ENST00000468789 / NM_001105078.4; = p.S360= on NM_004991.4) | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as rs185054275, COSV52969010; called by muse, mutect2, varscan2
- MFGE8 | c.579C>T p.V193= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV99183962; called by muse, mutect2, varscan2
- MTCP1 | c.21G>A p.G7= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV100749852; called by muse, mutect2, varscan2
- NUMBL | c.339C>T p.S113= | Silent (SNP) | VAF 18/168 reads (11%) | catalogued as rs376443919; called by muse, mutect2, varscan2
- PCDHB11 | c.1626C>T p.S542= | Silent (SNP) | VAF 43/83 reads (52%) | catalogued as COSV100697017; called by muse, mutect2, varscan2
- PIGR | c.1951C>T p.L651= | Silent (SNP) | VAF 52/125 reads (42%) | catalogued as COSV100732522; called by muse, mutect2, varscan2
- PNMT | c.696G>A p.V232= | Silent (SNP) | VAF 9/13 reads (69%) | catalogued as COSV99510622; called by muse, mutect2, varscan2
- PTPRO | c.1773A>T p.A591= | Silent (SNP) | VAF 67/161 reads (42%) | catalogued as COSV99840604; called by muse, mutect2, varscan2
- RAD50 | c.504A>G p.E168= | Silent (SNP) | VAF 46/57 reads (81%) | catalogued as rs997560035, COSV99529003; ClinVar: likely benign; called by muse, mutect2, varscan2
- TEKT5 | c.438G>C p.S146= | Silent (SNP) | VAF 41/188 reads (22%) | catalogued as COSV99296112, COSV99296121; called by muse, mutect2, varscan2
- TMEM130 | c.1087C>A p.R363= | Silent (SNP) | VAF 60/93 reads (65%) | catalogued as rs142570247, COSV59561389; called by muse, mutect2, varscan2
- VPS50 | c.2352A>T p.V784= | Silent (SNP) | VAF 18/123 reads (15%) | catalogued as COSV100004845; called by muse, mutect2, varscan2
- ZFP30 | c.441G>C p.L147= | Silent (SNP) | VAF 23/181 reads (13%) | catalogued as COSV100665926; called by muse, mutect2, varscan2
- ZNF18 | c.369C>T p.P123= | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as rs548673219, COSV59553123; called by muse, mutect2, varscan2
- CAMKK2 | c.-231C>T | 5'UTR (SNP) | VAF 8/17 reads (47%) | catalogued as COSV100242990; called by muse, mutect2, varscan2
- HAUS6 | c.1377-197G>T | Intron (SNP) | VAF 34/96 reads (35%) | catalogued as COSV100997846; called by muse, varscan2
- NXF5 | n.1270A>T | RNA (SNP) | VAF 107/134 reads (80%) | catalogued as COSV99534419; called by muse, mutect2, varscan2
